Somatic mutation profile of tumor specimen 0DK96R from CCDI case PBBXPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 18.2 years (6,643 days).
Specimen 0DK96R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c27d283-6ff1-43c6-bbb5-9381b1cb804c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK96E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e42bc403-3a8a-42ca-bbc6-93cd2e0811ba

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1365_1370del p.F456_Q457del (on ENST00000521381 / NM_181523.3; = p.F186_Q187del on NM_181504.4) | In Frame Del (DEL) | VAF 86/535 reads (16%) | hotspot (GDC flag); called by mutect2, varscan2
- PCDHB7 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 115/662 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.066); catalogued as rs373150563; called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 30/859 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM3 | c.1885G>C p.A629P | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AF196969.1 | c.-7C>G | 5'UTR (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
